FM case AD14884 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/0a75e574-4244-4565-a546-e35bd630a426

Female, 61.2 years: Renal cell carcinoma, NOS (ICD-O-3 8312/3) of the kidney; metastasis biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 35% (pathologist estimate recorded by GDC). Sample type: Metastatic.
